Somatic mutation profile of tumor specimen TCGA-DU-A6S7-01A (aliquot TCGA-DU-A6S7-01A-21D-A32B-08) from TCGA case TCGA-DU-A6S7, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 27.8 years (10,170 days).
Specimen TCGA-DU-A6S7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2527d1f9-d9c6-4b4d-8a15-c0fb7b6fefe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A6S7-10A (Blood Derived Normal), aliquot TCGA-DU-A6S7-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e203784-230e-4344-8b08-dd8215b16ad1

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Frame Shift Del 4, Silent 4, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 53/60 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC141 | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99837161; called by muse, mutect2, varscan2
- CEP44 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99639640; called by muse, mutect2, varscan2
- CPNE4 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV101456774; called by muse, mutect2, varscan2
- GPRASP1 | c.2402A>G p.D801G | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV100851045, COSV64356422; called by muse, mutect2
- HSPG2 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV101020918, COSV65977442; called by muse, mutect2, varscan2
- KATNAL1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101017080; called by muse, mutect2, varscan2
- LIPN | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.568); catalogued as rs748347735, COSV101356234; called by muse, mutect2, varscan2
- MTOR | c.6910T>C p.W2304R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816497; called by muse, mutect2, varscan2
- MYH1 | c.1626G>T p.M542I | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV99875410, COSV99876509; called by muse, mutect2, varscan2
- NSD3 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100388793; called by muse, mutect2, varscan2
- OGT | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.111); catalogued as COSV65483142; called by muse, mutect2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, mutect2, varscan2
- PI3 | c.322T>C p.S108P | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV99714242; called by muse, mutect2
- RPIA | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99376356; called by muse, mutect2, varscan2
- TRPC7 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs757025359, COSV61452096, COSV61454267; called by muse, mutect2, varscan2
- WNK3 | c.1627G>T p.V543F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100671823; called by muse, mutect2, varscan2
- ADAMTS17 | c.1371_1374del p.H457Qfs*25 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- ATRX | c.6338_6341del p.F2113Sfs*9 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | called by pindel, varscan2
- COBLL1 | c.2722_2723del p.D908Hfs*22 (on ENST00000392717; = p.D870Hfs*22 on NM_014900.5) | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by pindel, varscan2
- EIF3J | c.641_645del p.E214Afs*24 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- ARSD | c.1638C>T p.A546= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs762455762, COSV101144599; called by muse, mutect2, varscan2
- CELSR1 | c.6855C>T p.A2285= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs770140686, COSV53084124, COSV99420499; called by muse, varscan2
- COL22A1 | c.333C>T p.H111= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs369045292; called by muse, mutect2
- FOXS1 | c.21C>T p.P7= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs564111331, COSV54069208; called by muse, mutect2, varscan2
- ATP11A | c.*137A>G | 3'UTR (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99369397; called by muse, mutect2, varscan2
- OR2W5 | n.1067G>A | RNA (SNP) | VAF 12/93 reads (13%) | catalogued as rs532925117; called by muse, mutect2, varscan2
